Somatic mutation profile of tumor specimen TCGA-W5-AA2K-01A (aliquot TCGA-W5-AA2K-01A-11D-A46P-09) from TCGA case TCGA-W5-AA2K, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 75.9 years (27,718 days).
Specimen TCGA-W5-AA2K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4730e7df-a338-4d04-9343-cf35813f54d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-W5-AA2K-10A (Blood Derived Normal), aliquot TCGA-W5-AA2K-10A-01D-A46P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c1a6d1bc-2a16-435c-842c-22cf66d5c1a0

The open-access MAF lists 41 somatic variants for this specimen: 30 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 10, Frame Shift Ins 2, Frame Shift Del 2, Translation Start Site 1, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ELF3 | c.1009T>A p.Y337N | Missense Mutation (SNP) | VAF 27/34 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62839558; called by muse, mutect2, varscan2
- MUC16 | c.28693C>T p.P9565S | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.923); catalogued as COSV67468702; called by muse, mutect2, varscan2
- OR5AP2 | c.935G>A p.W312* | Nonsense Mutation (SNP) | VAF 19/40 reads (48%) | catalogued as rs1565031294, COSV100266101; called by muse, mutect2, varscan2
- RABEP2 | c.1439C>T p.S480F | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as rs1005110271, COSV62870938; called by muse, mutect2, varscan2
- SELENOO | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.038); catalogued as rs1038839589; called by muse, mutect2, varscan2
- SERPINF2 | c.611T>C p.I204T | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV60663800; called by muse, mutect2, varscan2
- SPANXN3 | c.71dup p.N24Kfs*2 | Frame Shift Ins (INS) | VAF 14/58 reads (24%) | catalogued as rs781940283; called by mutect2, varscan2
- TFIP11 | c.643G>C p.E215Q | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs980703232; called by muse, mutect2, varscan2
- TMEM209 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 12/36 reads (33%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.38); catalogued as rs1233108354; called by muse, mutect2, varscan2
- TRAV41 | c.79G>C p.E27Q | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as rs370846361; called by muse, mutect2, varscan2
- C2orf16 | c.581G>T p.G194V | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.858); called by muse, mutect2
- ERG | c.755C>T p.T252I (on ENST00000398919 / NM_001243428.1; = p.T245I on NM_182918.4) | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- EXPH5 | c.5011A>C p.N1671H | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); called by muse, mutect2
- GALM | c.598A>T p.T200S | Missense Mutation (SNP) | VAF 38/58 reads (66%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, mutect2, varscan2
- GUCY2F | c.850C>A p.L284M | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- HSD3B1 | c.304G>T p.V102L | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MUC16 | c.33868G>T p.D11290Y | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- NEBL | c.2537C>A p.T846K | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- NFRKB | c.1070C>A p.A357D (on ENST00000446488 / NM_001143835.2; = p.A382D on NM_006165.3) | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.069); called by muse, mutect2
- OR51F2 | c.103C>A p.L35I | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PIKFYVE | c.2526A>T p.R842S | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.308); called by muse, mutect2
- PSIP1 | c.1390C>A p.P464T | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.001); called by muse, mutect2
- RIOK2 | c.1480T>G p.S494A | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- SETX | c.7571del p.S2524* | Frame Shift Del (DEL) | VAF 19/39 reads (49%) | called by mutect2, pindel, varscan2
- SPRED1 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TM9SF2 | c.1430G>T p.W477L | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.658); called by muse, mutect2
- TMEM63A | c.2165dup p.H722Qfs*15 | Frame Shift Ins (INS) | VAF 21/39 reads (54%) | called by mutect2, pindel, varscan2
- TPCN1 | c.2122G>A p.G708S | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.46); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- TPTE | c.1046T>A p.V349D (on ENST00000618007 / NM_199261.4; = p.V331D on NM_199259.4) | Missense Mutation (SNP) | VAF 17/348 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- WNK2 | c.6848del p.G2283Afs*33 | Frame Shift Del (DEL) | VAF 10/41 reads (24%) | called by pindel, varscan2
- DUSP21 | c.195C>T p.G65= | Silent (SNP) | VAF 9/16 reads (56%) | called by muse, mutect2, varscan2
- IGKV1D-42 | c.336G>A p.Q112= | Silent (SNP) | VAF 51/67 reads (76%) | called by muse, mutect2, varscan2
- JADE3 | c.921G>A p.R307= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as rs782493489; called by muse, mutect2, varscan2
- KIT | c.144C>T p.V48= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV55410143; called by muse, varscan2
- MLPH | c.915G>T p.L305= | Silent (SNP) | VAF 24/45 reads (53%) | called by muse, mutect2, varscan2
- OR10S1 | c.579C>T p.C193= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as rs199631140, COSV73342784; called by muse, mutect2
- PRDM5 | c.822G>A p.K274= | Silent (SNP) | VAF 24/44 reads (55%) | called by muse, mutect2, varscan2
- SLC35E4 | c.141C>A p.A47= | Silent (SNP) | VAF 7/16 reads (44%) | called by muse, mutect2, varscan2
- TIGIT | c.213T>G p.A71= | Silent (SNP) | VAF 14/26 reads (54%) | called by muse, mutect2, varscan2
- XPR1 | c.156C>A p.A52= | Silent (SNP) | VAF 28/37 reads (76%) | called by muse, mutect2, varscan2
- SOHLH1 | c.*624C>A | 3'UTR (SNP) | VAF 4/32 reads (13%) | catalogued as rs868529486, COSV53682788; called by muse, mutect2
